Somatic mutation profile of tumor specimen TARGET-10-PARJAY-09A (aliquot TARGET-10-PARJAY-09A-01D) from TARGET case TARGET-10-PARJAY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,652 days).
Specimen TARGET-10-PARJAY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a08ec46-99cf-4bc9-b649-cfc75cd4b699.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARJAY-10A (Blood Derived Normal), aliquot TARGET-10-PARJAY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f00aaf4a-e72b-4159-9b77-00cb163e52c8

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 4, 3'UTR 2, Frame Shift Ins 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 73/183 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.2960G>A p.R987H (on ENST00000614293; = p.R957H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs201250586; called by muse, mutect2, varscan2
- CXXC1 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.618); catalogued as COSV53276775; called by muse, mutect2, varscan2
- GDI1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50132558; called by muse, mutect2, varscan2
- IGF2BP3 | c.898A>T p.K300* | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as rs1371233673, COSV51681276, COSV51682646; called by muse, mutect2, varscan2
- NOTCH1 | c.4775T>C p.F1592S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024854, COSV53033159; called by muse, mutect2, varscan2
- OR10G9 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1023000771, COSV66686800; called by muse, mutect2, varscan2
- SBNO1 | c.2911G>A p.A971T (on ENST00000420886; = p.A970T on NM_018183.5) | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57339398; called by muse, mutect2, varscan2
- USP7 | c.705_706insGCCCCCCT p.N236Afs*12 | Frame Shift Ins (INS) | VAF 11/25 reads (44%) | catalogued as COSV61217362; called by mutect2, pindel, varscan2
- SPESP1 | c.688dup p.I230Nfs*5 | Frame Shift Ins (INS) | VAF 96/224 reads (43%) | called by mutect2, varscan2
- BAGE2 | n.1029C>T | RNA (SNP) | VAF 47/360 reads (13%) | called by muse, mutect2, varscan2
- DNAAF3 | c.1238+42G>A | Intron (SNP) | VAF 40/99 reads (40%) | catalogued as rs758777169; called by muse, mutect2, varscan2
- GAP43 | c.*26C>G | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by mutect2, varscan2
- GPRC5A | c.*3299C>T | 3'UTR (SNP) | VAF 7/15 reads (47%) | catalogued as rs750055547; called by muse, mutect2, varscan2
- MMAB | c.421+95C>T | Intron (SNP) | VAF 19/42 reads (45%) | catalogued as rs756735952; called by muse, mutect2
- SMAD3 | c.207-21911G>A | Intron (SNP) | VAF 10/33 reads (30%) | catalogued as rs1441203817; called by muse, mutect2, varscan2
- ZNF606 | c.-51-696del | Intron (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel*
